Somatic mutation profile of tumor specimen 0DUME4 from CCDI case PBCLEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (630 days).
Specimen 0DUME4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d136ad9e-cf62-4b0a-a11f-a2f49e747ce0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d95b51ce-e816-4d9d-95b5-48a5d7ab5f9e

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 301/762 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- COL4A3 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 169/465 reads (36%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.979); catalogued as rs148686474, COSV67413775; called by muse, mutect2, varscan2
- POLA1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 96/566 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66888499; called by muse, varscan2
- TRMT9B | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 112/599 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs545539186; called by muse, mutect2, varscan2
- C11orf95 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 167/587 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2D | c.13102dup p.T4368Nfs*4 | Frame Shift Ins (INS) | VAF 151/550 reads (27%) | called by mutect2, varscan2
- SUFU | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 234/546 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- C3 | c.*56G>T | 3'UTR (SNP) | VAF 124/274 reads (45%) | called by muse, mutect2, varscan2
- CC2D1B | c.478-54T>C | Intron (SNP) | VAF 94/278 reads (34%) | called by muse, mutect2, varscan2
- MS4A2 | c.*66G>A | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, varscan2
